Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8D6, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8D6-01A (Primary Tumor).

Operative Procedure:
Thymectomy/and mediastinum dissection.

Pre-Operative Diagnosis:
As below.

Post-Operative Diagnosis:
As below.

Specimen Received:
Thymus

Final Pathologic Diagnosis:
Thymus, thymectomy:
Thymoma, WHO type B2 (see note).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:
The tumor is seen to breach the capsule, but definite invasion into the peri-thymic adipose tissue is not seen.

Gross Description:
The specimen is received in a single formalin filled container labeled with the patient's name and "thymus" and consists of a single portion of tan-yellow soft tissue measuring 19.6 x 11.2 x 1.2 cm. On one edge of the specimen there is a firm, well-circumscribed lesion measuring 4.9 x 4.5 x 3.1 cm. The overlying soft tissue is inked. Upon sectioning the cut surface reveals a homogenous, pale tan cut surface without evidence of hemorrhage or necrosis. Upon sectioning the remainder of the specimen the cut surface reveals unremarkable, tan-yellow fat. Representative sections of the tumor are submitted in cassettes "1-4" and a representative section of the adjacent, uninvolved tissue is submitted in cassette "5".

Microscopic Description:
A microscopic examination is performed.

Surgical Pathology Report

Taken: DOB: Gender: F Race: White

*7000-5
Thymoma, type B2, malignant 8584/3
Site: Thymus C37.9
9/26/13/14*

Dual/Synchronous Primary (Noted)		/

Source: NCI Genomic Data Commons file f54ea83e-0886-49a2-8831-dd69811fe6ba (TCGA-X7-A8D6.8162F9FE-3DEB-456D-8F53-3896972E60EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).